Somatic mutation profile of cancer-model specimen HCM-CSHL-0737-C18-85M (3D Organoid, passage 5; aliquot HCM-CSHL-0737-C18-85M-01D-A85C-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0737-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 28.1 years (10,259 days).
Specimen HCM-CSHL-0737-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2113b8b6-d05e-43a1-b09f-12c2df6cdbcc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0737-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0737-C18-10A-01D-A85C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7bf4e633-58dc-4892-afa4-5de07854947c

The open-access MAF lists 146 somatic variants for this specimen: 104 protein-altering or splice-affecting, 39 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 39, Nonsense Mutation 8, Frame Shift Del 3, Splice Region 2, In Frame Ins 1, In Frame Del 1, 5'Flank 1, Frame Shift Ins 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 213/496 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- PIK3CA | c.1636C>A p.Q546K | Missense Mutation (SNP) | VAF 189/486 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABTB2 | c.3070C>T p.R1024W | Missense Mutation (SNP) | VAF 197/414 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.73); catalogued as rs756226554; called by muse, mutect2, varscan2
- ACTA1 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 235/486 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.641); catalogued as rs148514635; called by muse, varscan2
- ADGRA2 | c.2657G>A p.R886Q | Missense Mutation (SNP) | VAF 213/821 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756095204, COSV55105542; called by muse, varscan2
- AFDN | c.2491G>C p.E831Q | Missense Mutation (SNP) | VAF 164/484 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV60061189; called by muse, mutect2, varscan2
- AGRN | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 300/630 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs763826900, COSV65067983; called by muse, varscan2
- AGRN | c.3370G>C p.E1124Q | Missense Mutation (SNP) | VAF 284/573 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs367954671; called by muse, mutect2, varscan2
- ANLN | c.980C>T p.T327M | Missense Mutation (SNP) | VAF 214/602 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as rs564754015, COSV56076129; called by muse, varscan2
- AP4B1 | c.218G>A p.C73Y | Missense Mutation (SNP) | VAF 257/564 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1485512805; called by muse, mutect2, varscan2
- APC | c.2510C>G p.S837* | Nonsense Mutation (SNP) | VAF 208/585 reads (36%) | catalogued as rs79512956, CD011083, CD084036, CM014886, COSV57338611, COSV57345932; ClinVar: other; called by muse, mutect2, varscan2
- ARMC4 | c.1567C>G p.H523D | Missense Mutation (SNP) | VAF 169/362 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs770607602; called by muse, mutect2, varscan2
- ARPP21 | c.910C>A p.Q304K | Missense Mutation (SNP) | VAF 118/328 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.449); catalogued as rs769481662; called by muse, varscan2
- C18orf63 | c.1595C>T p.S532L | Missense Mutation (SNP) | VAF 202/202 reads (100%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs1004661351, COSV101647133; called by muse, varscan2
- C2orf81 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 416/792 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as rs1439438922; called by muse, varscan2
- CDCA7L | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 238/702 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.158); catalogued as rs777536863; called by muse, varscan2
- CFAP47 | c.6262C>T p.R2088C | Missense Mutation (SNP) | VAF 96/526 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs950741875; called by muse, mutect2, varscan2
- CHST3 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 386/768 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.442); catalogued as rs866564371; called by muse, varscan2
- CPSF4 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 358/500 reads (72%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs201226770, COSV99462606; called by muse, mutect2, varscan2
- CYLC1 | c.1271del p.K424Rfs*69 | Frame Shift Del (DEL) | VAF 146/574 reads (25%) | catalogued as rs1385226543; called by mutect2, pindel, varscan2
- DNAJB11 | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 241/449 reads (54%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs1244847769; called by muse, mutect2, varscan2
- EML4 | c.802C>T p.R268* | Nonsense Mutation (SNP) | VAF 50/254 reads (20%) | catalogued as rs1056241625; called by muse, varscan2
- FAM160B1 | c.1549G>T p.G517* | Nonsense Mutation (SNP) | VAF 121/255 reads (47%) | catalogued as rs571805690; called by mutect2, varscan2
- FAM47C | c.1309C>T p.H437Y | Missense Mutation (SNP) | VAF 407/819 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.098); catalogued as rs1451902015; called by muse, mutect2, varscan2
- FIGNL2 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 486/1005 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1446150985; called by muse, varscan2
- FLNC | c.7484G>A p.R2495H | Missense Mutation (SNP) | VAF 246/959 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as rs757219498; ClinVar: uncertain significance; called by muse, varscan2
- FSCN3 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 379/1060 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs375234200, COSV50001153; called by muse, varscan2
- GNAZ | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 250/585 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as rs772358501, COSV50740020; called by muse, mutect2, varscan2
- GPR15 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 285/698 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752760213, COSV52520641, COSV52521171, COSV99423711; called by muse, varscan2
- GPR45 | c.679G>A p.V227M | Missense Mutation (SNP) | VAF 332/707 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.183); catalogued as COSV51524999; called by muse, mutect2, varscan2
- GTSE1 | c.1678C>T p.P560S | Missense Mutation (SNP) | VAF 284/568 reads (50%) | SIFT tolerated (0.8); PolyPhen benign (0.074); catalogued as rs1311586740, COSV101483229, COSV101483249; called by muse, varscan2
- KDM5C | c.2944C>T p.R982C | Missense Mutation (SNP) | VAF 407/833 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.159); catalogued as rs369353279; called by muse, mutect2, varscan2
- KIF26B | c.5255C>A p.T1752N | Missense Mutation (SNP) | VAF 207/853 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.109); catalogued as COSV63649630; called by mutect2, varscan2
- LLGL1 | c.1957G>C p.V653L | Missense Mutation (SNP) | VAF 252/258 reads (98%) | SIFT tolerated (0.13); PolyPhen benign (0.389); catalogued as rs752814889; called by muse, mutect2, varscan2
- MCM3AP | c.4526C>A p.A1509D | Missense Mutation (SNP) | VAF 186/446 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99386572; called by muse, varscan2
- PCDH11X | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 152/1274 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.011); catalogued as rs1321956313, COSV53446770; called by muse, varscan2
- PCDHGC5 | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 358/1011 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.204); catalogued as rs994009107; called by muse, varscan2
- PDZRN3 | c.2839G>A p.A947T | Missense Mutation (SNP) | VAF 413/413 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs560895860, COSV55195692; called by muse, mutect2, varscan2
- PGLYRP3 | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 173/330 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV51952623; called by muse, mutect2, varscan2
- PKD1L3 | c.2269G>A p.A757T | Missense Mutation (SNP) | VAF 308/501 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201602319; called by muse, mutect2, varscan2
- POM121L12 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 388/1177 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1051548292; called by muse, varscan2
- RBFOX1 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 549/860 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs747612014, COSV60947328, COSV60981803; called by muse, mutect2, varscan2
- RNLS | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 260/556 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.079); catalogued as COSV59291566; called by muse, mutect2, varscan2
- RYR2 | c.4828C>T p.R1610* | Nonsense Mutation (SNP) | VAF 291/605 reads (48%) | catalogued as rs794728738, COSV63680907, COSV63711227; ClinVar: uncertain significance; called by muse, varscan2
- SH2D4B | c.1054C>T p.R352W | Missense Mutation (SNP) | VAF 105/495 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764622468; called by muse, mutect2, varscan2
- SLC25A13 | c.1490C>T p.S497L | Missense Mutation (SNP) | VAF 117/508 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1487481217; called by muse, mutect2, varscan2
- SLC30A10 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 520/1051 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1257640243, COSV63076489; called by muse, varscan2
- SMARCD2 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 137/499 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.349); catalogued as rs773107708; called by muse, mutect2, varscan2
- SOGA3 | c.2080G>A p.D694N | Missense Mutation (SNP) | VAF 234/618 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as rs1367628607, COSV64108165; called by muse, varscan2
- SURF6 | c.995A>G p.K332R | Missense Mutation (SNP) | VAF 244/766 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.083); catalogued as rs781867605; called by muse, mutect2, varscan2
- TEX14 | c.3281C>T p.S1094L (on ENST00000240361 / NM_001201457.2; = p.S1088L on NM_198393.4) | Missense Mutation (SNP) | VAF 72/380 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs193920796, COSV53611227; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TIAM2 | c.3119G>A p.G1040D | Missense Mutation (SNP) | VAF 120/272 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.495); catalogued as rs1208105196, COSV59690566; called by muse, mutect2, varscan2
- TNFRSF8 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 334/601 reads (56%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs774218959; called by muse, varscan2
- VN1R5 | c.193_195del p.L65del | In Frame Del (DEL) | VAF 143/324 reads (44%) | catalogued as rs770080400; called by pindel, varscan2
- ZC3H12D | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 114/572 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775973883, COSV66324762; called by muse, varscan2
- ZMYND11 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 151/290 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs1275904257, COSV59076391; called by muse, mutect2, varscan2
- ZNF135 | c.33G>A p.P11= | Splice Region (SNP) | VAF 108/753 reads (14%) | catalogued as rs749105473, COSV57880403; called by muse, mutect2, varscan2
- ZNF185 | c.73G>A p.V25I | Missense Mutation (SNP) | VAF 670/1019 reads (66%) | SIFT tolerated (0.15); PolyPhen benign (0.214); catalogued as rs782480857, COSV59274028, COSV59274277; called by muse, mutect2, varscan2
- ZNF383 | c.475C>G p.L159V | Missense Mutation (SNP) | VAF 141/583 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.038); catalogued as rs372725712; called by muse, mutect2, varscan2
- ZNF385B | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 163/338 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200150920, COSV61176803; called by muse, mutect2, varscan2
- ADGRG6 | c.2183A>T p.N728I | Missense Mutation (SNP) | VAF 251/386 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, varscan2
- ALMS1 | c.3068C>A p.T1023N | Missense Mutation (SNP) | VAF 24/616 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.907); called by muse, mutect2
- CAMSAP2 | c.2298G>A p.M766I (on ENST00000236925 / NM_001297707.2; = p.M755I on NM_203459.3) | Missense Mutation (SNP) | VAF 240/494 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- CIC | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 134/880 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- CRLF3 | c.1274C>G p.S425C | Missense Mutation (SNP) | VAF 92/374 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by mutect2, varscan2
- CYRIA | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 127/265 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- DCDC1 | c.5312C>T p.P1771L (on ENST00000597505 / NM_001367979.1; = p.P878L on NM_020869.3) | Missense Mutation (SNP) | VAF 208/497 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- DCHS1 | c.4639G>A p.A1547T | Missense Mutation (SNP) | VAF 385/808 reads (48%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAAF5 | c.1648G>C p.E550Q | Missense Mutation (SNP) | VAF 249/829 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EYS | c.2764G>T p.G922* | Nonsense Mutation (SNP) | VAF 73/263 reads (28%) | called by muse, mutect2, varscan2
- FOXI2 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 548/1134 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, varscan2
- FSIP2 | c.12501del p.K4167Nfs*3 | Frame Shift Del (DEL) | VAF 74/203 reads (36%) | called by mutect2, pindel, varscan2
- GDF15 | c.137dup p.L46Ffs*253 | Frame Shift Ins (INS) | VAF 273/906 reads (30%) | called by mutect2, varscan2
- HSPA14 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 114/261 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, varscan2
- KCNS1 | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 400/821 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA0319L | c.1934T>C p.L645P | Missense Mutation (SNP) | VAF 212/464 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, varscan2
- KMT2A | c.8890G>A p.E2964K | Missense Mutation (SNP) | VAF 341/674 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LRP1B | c.2788G>T p.D930Y | Missense Mutation (SNP) | VAF 181/351 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- MALRD1 | c.723G>T p.L241F | Missense Mutation (SNP) | VAF 180/390 reads (46%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- MAP7D3 | c.600G>T p.M200I | Missense Mutation (SNP) | VAF 204/595 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by mutect2, varscan2
- MTHFD1L | c.1522C>T p.L508F | Missense Mutation (SNP) | VAF 194/341 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- MYO16 | c.4660G>A p.A1554T | Missense Mutation (SNP) | VAF 512/692 reads (74%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); called by muse, varscan2
- NETO1 | c.469G>T p.D157Y | Missense Mutation (SNP) | VAF 96/97 reads (99%) | SIFT deleterious (0); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- NLGN1 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 313/722 reads (43%) | called by muse, varscan2
- NLRP11 | c.379G>C p.D127H | Missense Mutation (SNP) | VAF 138/481 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NR5A2 | c.1540G>T p.E514* (on ENST00000367362 / NM_205860.3; = p.E468* on NM_003822.5) | Nonsense Mutation (SNP) | VAF 232/516 reads (45%) | called by muse, mutect2, varscan2
- OR2AG2 | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 342/783 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); called by muse, varscan2
- OR51M1 | c.448G>T p.G150C | Missense Mutation (SNP) | VAF 303/626 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- PAF1 | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 165/489 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PAGE4 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 164/332 reads (49%) | called by mutect2, varscan2
- PDX1 | c.561G>C p.E187D | Missense Mutation (SNP) | VAF 196/750 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- PLAAT1 | c.718C>A p.Q240K (on ENST00000650797; = p.Q135K on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 184/440 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, varscan2
- RHBDD3 | c.802G>C p.E268Q | Missense Mutation (SNP) | VAF 370/698 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SNTG2 | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 192/403 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- SZRD1 | c.4del p.E2? | Frame Shift Del (DEL) | VAF 249/514 reads (48%) | called by mutect2, pindel, varscan2
- TEX14 | c.363G>C p.R121S | Missense Mutation (SNP) | VAF 252/643 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- THAP7 | c.191G>A p.C64Y | Missense Mutation (SNP) | VAF 233/590 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TLN1 | c.781G>C p.D261H | Missense Mutation (SNP) | VAF 70/221 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- TNPO1 | c.2179C>T p.P727S | Missense Mutation (SNP) | VAF 200/513 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.363); called by muse, varscan2
- TTC34 | c.2665_2667dup p.C889dup | In Frame Ins (INS) | VAF 252/598 reads (42%) | called by pindel, varscan2
- TXLNG | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 338/741 reads (46%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.255); called by muse, varscan2
- UCHL5 | c.945G>A p.K315= | Splice Region (SNP) | VAF 113/256 reads (44%) | called by muse, mutect2, varscan2
- ULBP2 | c.566A>G p.D189G | Missense Mutation (SNP) | VAF 448/718 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, varscan2
- VWDE | c.875T>C p.F292S | Missense Mutation (SNP) | VAF 323/452 reads (71%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCG4 | c.561A>G p.A187= | Silent (SNP) | VAF 293/633 reads (46%) | catalogued as rs1356380440; called by muse, mutect2, varscan2
- AZI2 | c.426G>A p.V142= | Silent (SNP) | VAF 198/447 reads (44%) | called by muse, mutect2, varscan2
- CACNB2 | c.342C>T p.P114= (on ENST00000324631 / NM_201596.3; = p.P59= on NM_000724.4) | Silent (SNP) | VAF 214/402 reads (53%) | catalogued as rs368505003; ClinVar: likely benign; called by muse, varscan2
- CDH24 | c.489C>T p.S163= | Silent (SNP) | VAF 177/353 reads (50%) | called by muse, mutect2, varscan2
- CYP2A13 | c.648G>A p.T216= | Silent (SNP) | VAF 174/578 reads (30%) | catalogued as rs748928501, COSV57838446; called by muse, varscan2
- DOCK8 | c.267C>T p.D89= | Silent (SNP) | VAF 237/358 reads (66%) | catalogued as rs770313916, COSV66633563; ClinVar: benign; called by muse, mutect2, varscan2
- EFCAB6 | c.3624C>T p.R1208= | Silent (SNP) | VAF 146/379 reads (39%) | catalogued as rs763679512, COSV53057233; called by muse, mutect2, varscan2
- FANCC | c.1476C>T p.L492= | Silent (SNP) | VAF 159/541 reads (29%) | catalogued as COSV100002407; called by muse, mutect2, varscan2
- FRMPD2 | c.1839G>A p.K613= | Silent (SNP) | VAF 75/376 reads (20%) | catalogued as COSV59719813; called by muse, mutect2, varscan2
- FTCD | c.1188G>A p.P396= | Silent (SNP) | VAF 346/927 reads (37%) | called by muse, mutect2, varscan2
- GBF1 | c.5268G>A p.P1756= (on ENST00000369983 / NM_001377137.1; = p.P1755= on NM_004193.3) | Silent (SNP) | VAF 170/387 reads (44%) | catalogued as rs376650007; called by muse, mutect2, varscan2
- GPR149 | c.948G>A p.A316= | Silent (SNP) | VAF 179/473 reads (38%) | catalogued as rs199866600; called by muse, mutect2, varscan2
- GRID2IP | c.1599C>T p.G533= | Silent (SNP) | VAF 266/1004 reads (26%) | catalogued as rs901388221; called by muse, mutect2, varscan2
- IQCD | c.1164G>A p.K388= (on ENST00000416617 / NM_001330452.2; = p.K286= on NM_138451.3) | Silent (SNP) | VAF 375/734 reads (51%) | catalogued as COSV55320392; called by mutect2, varscan2
- KIFC2 | c.1461C>T p.G487= | Silent (SNP) | VAF 207/956 reads (22%) | called by muse, mutect2, varscan2
- LMLN2 | c.279C>T p.A93= | Silent (SNP) | VAF 190/458 reads (41%) | catalogued as rs894048004; called by muse, mutect2, varscan2
- LMTK3 | c.3702G>A p.A1234= | Silent (SNP) | VAF 284/954 reads (30%) | called by muse, varscan2
- LRRC36 | c.42C>A p.R14= | Silent (SNP) | VAF 334/1130 reads (30%) | called by muse, varscan2
- LRRC38 | c.480C>T p.N160= | Silent (SNP) | VAF 400/894 reads (45%) | catalogued as rs1306770647, COSV65791564; called by muse, varscan2
- MEGF10 | c.2703C>T p.V901= | Silent (SNP) | VAF 144/442 reads (33%) | catalogued as rs758284831, COSV57249271; called by muse, mutect2, varscan2
- MUC16 | c.11514G>A p.V3838= | Silent (SNP) | VAF 275/634 reads (43%) | catalogued as COSV67499352; called by muse, varscan2
- MYO7A | c.249C>T p.R83= | Silent (SNP) | VAF 286/651 reads (44%) | called by muse, mutect2, varscan2
- NAALADL2 | c.2124G>C p.L708= | Silent (SNP) | VAF 300/604 reads (50%) | called by muse, mutect2, varscan2
- OTUD6A | c.840C>T p.A280= | Silent (SNP) | VAF 350/739 reads (47%) | called by muse, mutect2, varscan2
- PCDH17 | c.1740G>A p.A580= | Silent (SNP) | VAF 171/685 reads (25%) | called by muse, mutect2, varscan2
- PREX2 | c.1947C>T p.F649= | Silent (SNP) | VAF 257/930 reads (28%) | catalogued as rs1246499482; called by muse, varscan2
- PRKG1 | c.612C>G p.L204= | Silent (SNP) | VAF 141/370 reads (38%) | called by muse, mutect2, varscan2
- RALGAPA2 | c.1206C>G p.V402= | Silent (SNP) | VAF 167/365 reads (46%) | catalogued as COSV52486329, COSV99173537; called by muse, mutect2, varscan2
- SLC32A1 | c.543C>T p.R181= | Silent (SNP) | VAF 532/1094 reads (49%) | called by muse, varscan2
- SLITRK2 | c.2064C>A p.I688= | Silent (SNP) | VAF 378/1292 reads (29%) | catalogued as rs187828904, COSV59423329; called by muse, varscan2
- SPTAN1 | c.645C>G p.L215= | Silent (SNP) | VAF 153/237 reads (65%) | called by muse, varscan2
- STRN3 | c.882C>T p.D294= | Silent (SNP) | VAF 212/470 reads (45%) | catalogued as rs746431353, COSV100670204, COSV62580790; called by muse, varscan2
- SUSD4 | c.798C>T p.H266= | Silent (SNP) | VAF 234/509 reads (46%) | catalogued as rs768479836, COSV59549543; called by muse, mutect2, varscan2
- SV2B | c.1452A>G p.S484= | Silent (SNP) | VAF 225/516 reads (44%) | called by muse, mutect2, varscan2
- SYT12 | c.1131C>T p.S377= | Silent (SNP) | VAF 268/541 reads (50%) | catalogued as rs758652256, COSV67354836; called by muse, mutect2, varscan2
- TDRD9 | c.288T>C p.D96= | Silent (SNP) | VAF 205/413 reads (50%) | catalogued as rs766564389; called by muse, mutect2, varscan2
- ZNF121 | c.717G>A p.R239= | Silent (SNP) | VAF 284/610 reads (47%) | catalogued as rs1250901283; called by muse, varscan2
- ZNF208 | c.1977T>C p.H659= | Silent (SNP) | VAF 286/1170 reads (24%) | called by muse, varscan2
- ZNF267 | c.2067A>G p.K689= | Silent (SNP) | VAF 698/1050 reads (66%) | called by muse, varscan2
- RPGR | c.2520+1242G>T | Intron (SNP) | VAF 268/560 reads (48%) | catalogued as COSV58835975; called by mutect2, varscan2
- SAMD8 | chr10:75111611 C>T | 5'Flank (SNP) | VAF 498/964 reads (52%) | called by muse, varscan2
- XIST | n.11261G>T | RNA (SNP) | VAF 205/411 reads (50%) | called by muse, mutect2, varscan2
